FM case AD16845 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/3a656ac0-450d-4652-a6de-51e6deea011b

Male, 54.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 25% (pathologist estimate recorded by GDC). Sample type: Tumor.
